HCMI case HCM-BROD-0047-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/babbc3cb-14b7-4894-b91d-c160f4cb48e0

Demographics
Sex at birth: male; Race: asian; Year of birth: 1953; Vital status: Dead; Days to death: 495 days (1.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 61.3 years (22,404 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -5 days.
   Recorded as not given: neoadjuvant treatment (type not reported).

Follow-up (3 entries)
- Days to follow up: 20 days; Karnofsky performance status: 80.
- Days to follow up: 386 days (1.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- IDH1 / IDH2 (IHC): Negative.
- MGMT methylation: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 66.4 kg; Height: 166 cm; BMI: 24.1.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0047-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0047-C71-02A-01-S2-HE: Section location: Bottom; Percent tumor cells: 17; Percent tumor nuclei: 77; Percent normal cells: 5; Percent necrosis: 75; Percent stromal cells: 3; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0047-C71-02A-01-S1-HE: Section location: Top; Percent tumor cells: 61; Percent tumor nuclei: 94; Percent normal cells: 4; Percent necrosis: 30; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0047-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0047-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
- Sample HCM-BROD-0047-C71-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen.
